Gene-level copy-number profile of tumor specimen C3N-02928-01 (profiled together with C3N-02928-02) from CPTAC case C3N-02928, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.0 years (23,733 days).
Specimen C3N-02928-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9c10e9c-3564-4510-9395-0978f6fc84a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02928-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/08d08a79-b457-4c9d-bd64-cf924b352137

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 2; copy number 2: 6,098; copy number 3: 124; copy number 4: 46,355; copy number 5: 337; copy number 6: 4,383; copy number 7: 138; copy number 8: 217; copy number 9: 152; copy number 10: 324; copy number 11: 167; copy number 13: 42; copy number 14: 18; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,304,326–23,438,700, 41 genes: IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 384 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,306,368–41,043,890, 144 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr1:45,786,987–46,570,255, 23 genes, copy number 11 (within-gene range 7–11): MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN.
- chr1:47,760,528–50,023,954, 27 genes, copy number 9 (within-gene range 4–9): TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1, AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1, AGBL4-IT1, AL390023.1, ZNF859P.
- chr1:52,726,453–52,827,336, 1 gene, copy number 9 (within-gene range 4–9): ZYG11B.
- chr1:52,772,194–53,841,832, 41 genes, copy number 9: RPS13P2, RNU6-969P, ZYG11A, AC099677.3, ECHDC2, AC099677.1, AC099677.2, SCP2, AC099677.4, AC099677.6, AC099677.5, H3P2, RRAS2P1, TUBBP10, PODN, AL445183.1, HIGD1AP11, SLC1A7, AL445183.2, AL606760.4, CPT2, AL606760.2, CZIB, AL606760.3, MAGOH, AL606760.1, LRP8, AL355483.3, AL355483.1, AL355483.2, LINC01771, AC119428.2, AC119428.1, LINC02812, SLC25A3P1, DMRTB1, GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2.
- chr1:55,329,288–56,918,223, 22 genes, copy number 9–13: AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A.
- chr1:56,994,778–58,546,734, 1 gene, copy number 9 (within-gene range 8–14): DAB1.
- chr1:57,860,532–61,654,908, 40 genes, copy number 9: DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.1.
- chr1:62,975,751–64,693,058, 39 genes, copy number 9–14: LINC01739, AL162400.3, AL162400.1, AL162400.2, AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, UBE2U, RNU7-62P, CACHD1, MIR4794.
- chr7:15,611,212–17,942,922, 36 genes, copy number 9–13: MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1.
- chr7:25,547,762–26,276,606, 10 genes, copy number 9: AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
